Somatic mutation profile of tumor specimen MP2PRT-PASYVA-TMP1-A (aliquot MP2PRT-PASYVA-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASYVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,498 days).
Specimen MP2PRT-PASYVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df23ea8-8845-4f7d-9c16-a7ce294e651d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYVA-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e68d055d-5cbe-4826-8716-fd58765ce015

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.1387G>A p.V463I (on ENST00000297504 / NM_001282291.2; = p.V446I on NM_007188.5) | Missense Mutation (SNP) | VAF 205/422 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370506479; called by muse, mutect2, varscan2
- ATP8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650033, COSV54942586; called by muse, mutect2, varscan2
- CR2 | c.308G>C p.R103T | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as rs1325014294; called by muse, mutect2
- DNAH7 | c.9887C>T p.A3296V | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs144753545; called by muse, mutect2, varscan2
- FOXS1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 329/684 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370481154; called by muse, mutect2, varscan2
- MYOM3 | c.2715C>G p.I905M | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV58391425; called by muse, mutect2, varscan2
- NR3C2 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 36/312 reads (12%) | catalogued as rs1553995034; called by muse, mutect2, varscan2
- SOX30 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 298/592 reads (50%) | catalogued as COSV99398651; called by muse, mutect2, varscan2
- TEX10 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 29/205 reads (14%) | catalogued as COSV66515241; called by muse, mutect2, varscan2
- TEX13B | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 161/291 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as COSV100258289; called by muse, mutect2, varscan2
- AC013470.2 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 145/298 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CCDC110 | c.1531A>C p.I511L | Missense Mutation (SNP) | VAF 5/134 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2
- FLG2 | c.6602A>G p.H2201R | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.350_351del p.P117Lfs*? | Frame Shift Del (DEL) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- TRIP13 | c.356T>A p.I119K | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- C10orf71 | c.3978C>T p.D1326= | Silent (SNP) | VAF 106/586 reads (18%) | catalogued as rs1172274516, COSV60515452; called by muse, mutect2, varscan2
- CPAMD8 | c.4029G>A p.A1343= (on ENST00000651564; = p.A1296= on NM_015692.5) | Silent (SNP) | VAF 34/338 reads (10%) | catalogued as rs774465692, COSV71596615; called by muse, mutect2, varscan2
- RNF31 | c.1407G>T p.L469= | Silent (SNP) | VAF 54/548 reads (10%) | called by muse, mutect2
- RP1 | c.2889C>T p.P963= | Silent (SNP) | VAF 88/230 reads (38%) | catalogued as rs1018277430; called by muse, mutect2, varscan2
- SP2 | c.726G>A p.K242= | Silent (SNP) | VAF 15/476 reads (3%) | called by muse, mutect2
- TYRP1 | c.1095C>A p.P365= | Silent (SNP) | VAF 75/256 reads (29%) | called by muse, mutect2, varscan2
